Gene-level copy-number profile of tumor specimen TCGA-C5-A907-01A from TCGA case TCGA-C5-A907, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB2; Tumor grade: G2; Age at diagnosis: 47.4 years (17,304 days).
Specimen TCGA-C5-A907-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CESC.4bf3bf35-46c9-4f3b-beab-282f949e19bc.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-C5-A907-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/58e6ea0d-ac17-4792-a65f-d8ddbbbcf48c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 22; copy number 1: 3,351; copy number 2: 49,531; copy number 3: 5,444; copy number 4: 1,160; copy number 5: 266; copy number 6: 12; copy number 7: 32.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-C5-A907-01A-11D-A37M-01): tumor purity 0.61, ploidy 2.03, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 22 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:186,286,094–187,712,329, 22 genes (within-gene range 0–2): F11-AS1, AC109517.1, SLC25A5P6, AC018709.1, RNU6-1055P, MTNR1A, FAT1, AC107050.1, AC108865.1, AC108865.2, MRPS36P2, AC110772.1, AC110772.2, AC108046.1, LINC02374, AC097652.1, LINC02514, LINC02515, AC093763.2, AC093763.1, LINC02492, AC097521.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 310 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr19:30,553,956–30,668,647, 2 genes, copy number 5: AC011504.1, AC011478.1.
- chr19:32,127,334–32,485,895, 5 genes, copy number 5 (within-gene range 3–5): AC074139.1, RNA5SP472, ZNF507, AC007773.1, DPY19L3.
- chr19:34,956,354–35,528,351, 41 genes, copy number 5 (within-gene range 4–5): ZNF792, GRAMD1A, AC020907.3, AC020907.4, SCN1B, HPN, HPN-AS1, AC020907.1, AC020907.6, FXYD3, MIR6887, LGI4, AC020907.5, FXYD1, AC020907.2, FXYD7, FXYD5, FAM187B, FAM187B2P, LSR, AC002128.2, AC002128.1, USF2, HAMP, MAG, CD22, U62631.1, MIR5196, FFAR1, FFAR3, GPR42, EEF1A1P7, LINC01531, AC002511.3, RN7SL491P, AC002511.2, AC002511.1, FFAR2, KRTDAP, DMKN, SBSN.
- chr19:41,024,268–42,390,297, 80 genes, copy number 5 (broad region; genes not listed).
- chr19:42,401,514–42,442,946, 3 genes, copy number 5: LIPE, AC011497.1, CXCL17.
- chr19:55,006,193–56,197,920, 85 genes, copy number 5–6 (within-gene range 3–6) (broad region; genes not listed).
- chr19:57,571,566–58,605,223, 94 genes, copy number 5–7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 3,351. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
